Somatic mutation profile of tumor specimen BA2239D (aliquot aq-BA2239D) from BEATAML1.0 case 2326, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,291 days).
Specimen BA2239D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c44eeea4-37c5-4309-9032-7f61d5f9d8a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2338D (Solid Tissue Normal), aliquot aq-BA2338D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29059df8-2cb9-4fa1-bbef-064fe8150fa1

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- PTPN11 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 72/163 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918463, CM021134, CM060447, COSV61005134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDK12 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs376614675, COSV71002143; called by muse, mutect2, varscan2
- WDR87 | c.4964C>T p.A1655V | Missense Mutation (SNP) | VAF 144/352 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as rs141440839, COSV58200271; called by muse, mutect2, varscan2
- HUNK | c.647A>T p.Y216F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NOTCH3 | c.4377C>G p.H1459Q | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PUF60 | c.614C>G p.P205R (on ENST00000526683 / NM_001362896.2; = p.P188R on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- APOL6 | c.549A>G p.K183= | Silent (SNP) | VAF 142/340 reads (42%) | called by muse, mutect2, varscan2
- PAMR1 | c.840C>T p.C280= (on ENST00000619888 / NM_001001991.3; = p.C297= on NM_015430.4) | Silent (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- RELN | c.7467G>A p.G2489= | Silent (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
